Somatic mutation profile of tumor specimen C3N-01898-04 (aliquot CPT0162380036) from CPTAC case C3N-01898, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.1 years (17,926 days).
Specimen C3N-01898-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7760f3a-6739-493e-b202-7adc85ae65a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01898-31 (Blood Derived Normal), aliquot CPT0162430002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1adc34bb-86de-47fa-833a-339c6e65088e

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 23/395 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- CSMD3 | c.2530C>T p.R844W (on ENST00000297405 / NM_001363185.1; = p.R740W on NM_052900.3) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777713609, COSV52105465; called by muse, mutect2
- PDYN | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 10/303 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as rs1393045758, COSV99453450; called by muse, mutect2
- RIMBP2 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs772503598, COSV99900069, COSV99900431; called by muse, mutect2
- RTL1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs1216914274; called by muse, mutect2
- TOP3B | c.2066C>T p.P689L | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs769215648; called by muse, mutect2
- WDR45 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs782798113; called by muse, mutect2
- CD109 | c.1677A>G p.I559M | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- COL6A5 | c.3238G>A p.G1080R | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TBX22 | c.965C>T p.S322L | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- TKTL1 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.403); called by muse, mutect2
- ATRX | c.3774G>T p.V1258= | Silent (SNP) | VAF 9/300 reads (3%) | called by muse, mutect2
- IGHV1-46 | c.336G>T p.V112= | Silent (SNP) | VAF 18/372 reads (5%) | catalogued as rs539648580; called by muse, mutect2
- MAMLD1 | c.1314C>T p.T438= | Silent (SNP) | VAF 18/456 reads (4%) | catalogued as rs782756914; called by muse, mutect2
- RAB40B | c.393G>A p.A131= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as rs769582459, COSV53916677; called by muse, mutect2
- KRT8P11 | n.933C>T | RNA (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- SMARCA4 | c.1593+165G>A | Intron (SNP) | VAF 20/452 reads (4%) | catalogued as rs1437073300; called by muse, mutect2
